Gene-level copy-number profile of tumor specimen TARGET-10-PATSIY-09A from TARGET case TARGET-10-PATSIY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,404 days).
Specimen TARGET-10-PATSIY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.cfd46bf6-4e86-5d08-9413-adc188da388c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATSIY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate.
https://portal.gdc.cancer.gov/files/446048f0-1c44-4cfa-a87d-79d30c293d1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 2,437; copy number 2: 57,698; copy number 3: 58; copy number 4: 27.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,311,808, 9 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,636,924–142,793,368, 26 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr18:12,785,478–12,929,643, 3 genes (within-gene range 0–2): PTPN2, STK25P1, EIF4A2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
